Gene-level copy-number profile of tumor specimen BLGSP-71-17-00235-01B from CGCI case BLGSP-71-17-00235, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 38.5 years (14,077 days).
Specimen BLGSP-71-17-00235-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c2f3d064-ccd8-48ea-afc4-f992e22c69c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-17-00235-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,304 have no estimate.
https://portal.gdc.cancer.gov/files/45359b09-09d2-4c72-8d75-f31a46801107

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 3,536; copy number 2: 44,941; copy number 3: 8,419; copy number 4: 1,165; copy number 5: 202; copy number 6: 28; copy number 7: 2; copy number 9: 1; copy number 11: 2; copy number 13: 4; copy number 15: 2; copy number 18: 1; copy number 21: 5; copy number 22: 1; copy number 25: 1; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:43,109,866–60,964,196, 8 genes: FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 250 genes in 71 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,003,300–9,088,478, 3 genes, copy number 5: SLC2A7, SLC2A5, AL158048.1.
- chr2:47,690,716–47,810,063, 5 genes, copy number 5 (within-gene range 4–5): AC079250.1, MSH6, NME2P2, AC006509.1, U6.
- chr2:61,416,887–61,538,741, 5 genes, copy number 5: AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3.
- chr2:88,811,186–88,861,563, 2 genes, copy number 5 (within-gene range 4–5): MALLP2, AC244205.1.
- chr2:88,857,161–89,203,906, 34 genes, copy number 5: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1.
- chr2:89,266,494–89,600,680, 9 genes, copy number 5: IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr3:169,902,980–170,181,749, 12 genes, copy number 5: KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P.
- chr3:187,932,764–188,003,990, 4 genes, copy number 6: AC068295.1, LINC01991, AC092941.1, AC092941.2.
- chr4:70,628,744–70,704,491, 7 genes, copy number 5 (within-gene range 3–5): ENAM, AC009570.2, JCHAIN, UTP3, RNU6-520P, RNU6-784P, AC009570.1.
- chr4:143,336,762–143,474,568, 4 genes, copy number 5 (within-gene range 3–5): GAB1, MIR3139, AC097658.1, AC097658.3.
- chr6:41,934,934–42,050,357, 3 genes, copy number 5: CCND3, RNU6-761P, AL513008.1.
- chr6:53,267,398–53,369,009, 6 genes, copy number 5: ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33.
- chr6:89,926,528–90,363,912, 7 genes, copy number 5: BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464.
- chr6:158,765,741–158,864,502, 4 genes, copy number 5: EZR, EZR-AS1, OSTCP1, AL627422.2.
- chr7:50,095,883–50,275,622, 4 genes, copy number 5 (within-gene range 2–5): SPATA48, AC020743.1, AC020743.2, AC020743.3.
- chr7:74,650,231–74,851,551, 5 genes, copy number 5: GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2.
- chr7:102,637,049–102,690,469, 4 genes, copy number 6–18 (within-gene range 2–18): AC105052.3, SPDYE2B, POLR2J2, RASA4DP.
- chr8:11,421,476–11,564,694, 3 genes, copy number 5–7 (within-gene range 2–7): FAM167A, BLK, AC022239.1.
- chr8:80,967,810–81,112,068, 3 genes, copy number 5: PAG1, AC022778.1, AC079209.2.
- chr9:547,135–685,555, 4 genes, copy number 5: AL392089.1, RNU6-1327P, EIF1P1, AL136979.1.
- chr9:37,046,835–37,384,434, 11 genes, copy number 5–6: AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA, RNU6-677P, LINC01627.
- chr9:61,581,813–61,662,690, 4 genes, copy number 5–15: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:61,865,755–61,911,022, 4 genes, copy number 13–22: AL391987.4, AL391987.3, Y_RNA, FAM242E.
- chr10:96,743,167–96,750,899, 2 genes, copy number 5: RNU6-1274P, RPL13AP5.
- chr11:65,445,541–65,488,896, 4 genes, copy number 5: AP000769.4, AP000769.1, LINC02736, AP000769.6.
- chr11:82,973,133–83,111,442, 8 genes, copy number 5 (within-gene range 4–5): RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5.
- chr11:121,426,645–121,453,013, 2 genes, copy number 6 (within-gene range 3–6): AP002365.1, AP000977.1.
- chr11:128,458,761–128,587,558, 3 genes, copy number 5: ETS1, MIR6090, ETS1-AS1.
- chr12:92,420,094–92,531,324, 5 genes, copy number 5–6: CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1.
- chr13:30,419,519–30,429,758, 2 genes, copy number 6: LINC01058, UBE2L5.
- chr13:40,931,924–41,061,440, 2 genes, copy number 6 (within-gene range 3–6): ELF1, RGS17P1.
- chr14:63,734,697–63,736,505, 2 genes, copy number 6: EIF2S2P1, RNU7-116P.
- chr14:65,236,480–65,318,790, 4 genes, copy number 5: AL355076.2, RPL21P7, AL355076.1, PTBP1P.
- chr15:92,819,540–92,949,230, 2 genes, copy number 5 (within-gene range 2–5): CHASERR, AC013394.1.
- chr17:64,927,634–65,056,740, 9 genes, copy number 5 (within-gene range 2–5): AC103810.1, AC103810.4, AC037487.4, AC103810.8, AC037487.1, AC037487.3, SLC16A6P1, AMZ2P1, GNA13.
- chr17:68,206,076–68,257,712, 2 genes, copy number 5 (within-gene range 4–5): AMZ2, AC005332.1.
- chr18:32,769,795–32,779,286, 2 genes, copy number 5 (within-gene range 3–5): AC012123.1, AC012123.2.
- chr20:47,391,925–47,656,877, 5 genes, copy number 5 (within-gene range 2–5): LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3.
- chr21:43,414,483–43,479,534, 4 genes, copy number 9–25: SIK1, LINC00319, LINC00313, AP001048.1.
- chr22:18,605,355–18,625,289, 5 genes, copy number 21: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2.

Autosomal genes at a single copy (total copy number 1): 1,232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
